Surgical pathology report (de-identified scan), TCGA case TCGA-KB-A6F5, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University Health Network, Toronto, specimen TCGA-KB-A6F5-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: M

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Lymph-Node: Para Esophageal
2. Stomach Resection: Total stomach and proximal esophagus qs on esophagus margin
3. Esophagus: Final esophageal margin #1
4. Esophagus: Final esophageal margin #2

Diagnosis

1. Lymph-Node: Para Esophageal:
- lymph node x1: negative for carcinoma

2. Stomach and distal esophagus, total gastrectomy and distal esophagectomy:
- adenocarcinoma of proximal stomach, moderately to poorly differentiated, intestinal type, extending into distal oesophagus, invading perigastric fat – see synoptic data and comment
- metastatic adenocarcinoma in 4/16 lymph nodes
- resection margins: negative for carcinoma

- chronic atrophic pan-gastritis with marked intestinal metaplasia

3. Esophagus: Final esophageal margin #1:
- negative for carcinoma

4. Esophagus: Final esophageal margin #2:
- negative for carcinoma.

ICD-O-3
Adenocarcinoma, intestinal
Type 8144/3
Site Gastroesophageal junction
path Gastric fundus
JL 6/28/13

Comment

2. The tumor has features of an intestinal type adenocarcinoma and is focally poorly differentiated. There is chronic pangastritis with marked intestinal metaplasia. No H. pylori are identified.

Synoptic Data

Clinical History:	Not known
Specimen:	Stomach
	Distal esophagus
Procedure:	Total gastrectomy
Tumor Site:	Fundus
	Body - Anterior wall
	Body - Posterior wall

[page 2 of 4]
Surgical Pathology Consultation Report

Tumor Size:	Body - Lesser curvature Body - Greater curvature Greatest dimension: 11.5 cm Additional dimension: 7.5 cm Additional dimension: 1.7 cm
Histologic Type:	Adenocarcinoma, intestinal type
Histologic Grade:	G3: Poorly differentiated
Microscopic Extent of Tumor:	Tumor invades subserosal connective tissue
Proximal Margin:	Uninvolved by invasive carcinoma Carcinoma in situ/adenoma not identified at proximal margin
Distal Margin:	Uninvolved by invasive carcinoma Carcinoma in situ/adenoma not identified at distal margin
Omental (Radial) Margin:	Uninvolved by invasive carcinoma
Deep Margin:	Deep margin not applicable
Status of All Margins:	All margins uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 11.0 mm Closest margin: Proximal margin
Treatment Effect:	No prior treatment
Lymph-Vascular Invasion:	Present
Perineural Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor invades subserosal connective tissue, without involvement of visceral peritoneum or adjacent structures
Regional Lymph Nodes (pN):	pN2: Metastasis in 3 to 6 perigastric lymph nodes Number of lymph nodes examined: 16 Number of lymph nodes involved: 4
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Intestinal metaplasia Other gastritis: chronic atrophic gastritis

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen container labeled with the patient's name and as " para esophageal" contains two pieces of yellowish black nodal tissue measuring 0.4 x 0.4 x 0.2 cm and 0.6 x 0.3 x 0.2 cm received in 10% buffered formalin.
1A submitted in toto

2. STOMACH RESECTION FOR TUMOR (INCLUDES GE JUNCTION TUMORS)

GROSS EXAMINATION

RESECTION SPECIMEN: e.g. Total stomach, subtotal and proximal esophagus on the esophageal margin,
perigastric fat and omentum

FIXATION: Fixed

DIMENSIONS:

Length along lesser curvature 14.5 cm
Length along greater curvature 30 cm

[page 3 of 4]
Surgical Pathology Consultation Report

Circumference of distal gastric margin 8 cm
Circumference of proximal gastric margin n/a
Length of tubular esophagus if present 5-cm
circumference of tubular esophagus if present 5-cm

TUMOR:

LOCATION:

- cardia, fundus, GEJ, body
- Greater and lesser curvature
- Anterior and posterior wall
- 90% of tumor located in the stomach

- CONFIGURATION: exophytic with ulcerative center, annular/circumferential

- DIMENSIONS: Diameters 11.5 cm in circumference, 7.5 cm in length
Depth 1.7 cm

- DESCRIPTIVE CHARACTERISTICS: solid and homogeneous tan white on cut surface

- PERFORATION: no

DISTANCE FROM MARGINS:

- PROXIMAL 1.1 cm
- DISTAL 10.0 cm
- RADIAL 9.0 cm (non-peritonealized soft tissue margin closest to deepest tumor penetration)

ESTIMATED DEPTH OF INVASION: perigastric fat

LESIONS IN NONCANCEROUS STOMACH: None

LYMPH NODES: Multiple perigastric lymph nodes along the greater and lesser curvatures ranging in size from 0.3 to 3.0 cm.

ADDITIONAL STRUCTURESS: The greater omentum measures 37 x 17 x 2 cm. On serially sectioning no nodules identified.

Tissue is stored frozen

Representative Sections:

2A, 2B esophageal resection margin en face, frozen section blocks resubmitted

2C-2F one full length section of tumor from esophageal end to gastric wall just distal to tumor, includes a section of lymph node)

Both ends painted with India ink-they are NOT MARGINS).

2G, 2H, tumor with extension into perigastric fat and the remainder of greater curvature lymph node from block 2E.

2I tumor with a section of lymph node from lesser curvature.

2J tumor abutting serosa

2K gastric wall adjacent to tumor.

2L gastric body.

2M gastric antrum.

2N pylorus.

2O-2S omentum.

Lesser curvature lymph nodes:

2T, 2U multiple lymph nodes, each block.

2V, one lymph node bisected

2W one lymph node trisected

2X, 2Y representative sections from one large lymph node.

Greater curvature lymph nodes:

[page 4 of 4]
Surgical Pathology Consultation Report

2Z multiple lymph nodes
2AA, 2AB one lymph node, bisected, each block.
2AC, 2AD query quadrisected lymph node vs splenule.

ADDITIONAL BLOCKS:

2AE-2AF stomach < 5cm from tumour
2AG-2AH stomach > 5cm from tumour
2AI distal resection margin, en face

3. The specimen container labeled with the patient's name and as "final esophageal margin #1" contains a circular ring of tan tissue, grossly consistent with esophagus measuring 3 x 1.2 x 1.1 cm received in 10% buffered formalin. There is a staple line along one side of the specimen. No gross abnormality noted.
3A full face section opposite to staple line en face

4. The specimen container labeled with the patient's name and as "final esophageal margin #2" contains a piece of gray-tan, partly hemorrhagic tissue, grossly consistent with esophagus measuring 4.5 x 1.2 x 0.5 cm received in 10% buffered formalin. The surface of the tissue is smooth to slightly nodular. No staple line is identified.
4A, 4B, bisected and submitted in toto

Quick Section Diagnosis

2A,B (esophageal margin): negative for carcinoma. Reviewed with

H ¹ AA Discrepancy		✓

Source: NCI Genomic Data Commons file c4984be8-28ae-4d9a-9fe9-3b1ef7d38387 (TCGA-KB-A6F5.85EA626E-56D5-413B-9E90-1DD636BAAEE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).